Gene-level copy-number profile of tumor specimen HCM-CSHL-0859-C22-01A from HCMI case HCM-CSHL-0859-C22, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 62.9 years (22,982 days).
Specimen HCM-CSHL-0859-C22-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1f3b5a86-0429-4b8a-b401-39726d8c1c05.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0859-C22-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/e4f518ee-c8b2-4d15-b709-b2ae39bc67c9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 547; copy number 1: 13,438; copy number 2: 40,781; copy number 3: 3,826; copy number 4: 123; copy number 5: 46; copy number 6: 29; copy number 7: 28; copy number 9: 46; copy number 10: 31; copy number 11: 17; copy number 12: 2.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,638,285–25,089,151, 35 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3, IZUMO3, AL353811.1, RMRPP5, RN7SKP120.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 199 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:39,052,013–39,287,920, 13 genes, copy number 5: WDR48, GORASP1, TTC21A, MIR6822, CSRNP1, AC092053.3, AC092053.2, Metazoa_SRP, XIRP1, AC092053.6, DSTNP4, CX3CR1, AC092053.1.
- chr3:39,808,914–43,106,079, 75 genes, copy number 7–11 (broad region; genes not listed).
- chr3:86,235,321–87,276,584, 11 genes, copy number 5–10: RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1.
- chr3:87,641,412–88,319,022, 10 genes, copy number 6: AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1.
- chr6:41,736,711–42,452,051, 25 genes, copy number 6–11: PGC, AL365205.4, FRS3, AL365205.1, PRICKLE4, TOMM6, USP49, AL365205.3, AL365205.2, AL160163.1, MED20, Y_RNA, BYSL, CCND3, RNU6-761P, AL513008.1, TAF8, AL512274.1, C6orf132, AL096814.1, AL096814.2, GUCA1A, GUCA1B, MRPS10, TRERF1.
- chr6:46,159,185–47,832,780, 29 genes, copy number 5: ENPP5, ACTG1P9, RCAN2, AL359633.1, AL035670.1, CYP39A1, SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1, ADGRF1, TNFRSF21, B3GNTL1P2, AL355353.1, CD2AP, Y_RNA, AL358178.1, ADGRF2, ADGRF4, RN7SKP116, AL356421.2, AL356421.1, OPN5, RNU1-105P.
- chr9:61,615,835–61,662,690, 3 genes, copy number 5–7: FAM242D, Y_RNA, AL935212.1.
- chr10:50,623,466–53,766,614, 32 genes, copy number 10–12 (within-gene range 1–13): SGMS1-AS1, SHQ1P1, BEND3P1, NUTM2HP, AL589794.1, CTSLP4, PGGT1BP1, AL589794.2, ASAH2B, A1CF, AL512366.1, CCDC58P2, AL731537.2, PRKG1, AL731537.1, AC022537.1, MIR605, AC069079.1, RSU1P3, CSTF2T, PRKG1-AS1, DKK1, RPL31P44, THAP12P3, LNCAROD, MBL2, Y_RNA, LINC02672, SNRPEP8, AC036101.1, RNA5SP318, AL365496.1.
- chr10:56,357,227–56,361,273, 1 gene, copy number 6: ZWINT.

Autosomal genes at a single copy (total copy number 1): 11,094. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
